MMRF case MMRF_2237 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/316127f5-8d88-4434-a760-eb3caa8d383a

Demographics
Sex at birth: male; Ethnicity: not hispanic or latino; Age at index: 45 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.1 years (16,829 days); ISS stage: I; Days to last known disease status: 807 days (2.2 years); Days to last follow up: 807 days (2.2 years).
   Treatment given: Therapeutic agents: Carfilzomib + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -16 (ECOG 2): M Protein 3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.09 mg/dL; Immunoglobulin G 4.12 g/L; Immunoglobulin A 44.1 g/L; Immunoglobulin M 0.18 g/L; Beta 2 Microglobulin 2.7 µg/mL; Lactate Dehydrogenase 1.55 µkat/L; Hemoglobin 7.44 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 185 ×10⁹/L; Creatinine 96.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.5 mmol/L; Albumin 37 g/L; Total Protein 11.3 g/dL; Glucose 4.68 mmol/L; C-Reactive Protein 0.565 mg/dL.
- Day 92 (ECOG 1): M Protein 0.5 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.05 mg/dL; Immunoglobulin G 2.91 g/L; Immunoglobulin A 11.5 g/L; Immunoglobulin M 0.14 g/L; Lactate Dehydrogenase 2.57 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 4.8 ×10⁹/L; Platelets 135 ×10⁹/L; Creatinine 88.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.3 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 6.44 mmol/L.
- Day 176 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.59 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.81 mg/dL; Immunoglobulin G 2.65 g/L; Immunoglobulin A 0.35 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 3.2 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 8.4 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 214 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.2 mmol/L; Albumin 36 g/L; Total Protein 5.3 g/dL; Glucose 4.68 mmol/L.
- Day 261 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.41 mg/dL; Immunoglobulin G 6.46 g/L; Immunoglobulin A 0.43 g/L; Immunoglobulin M 0.52 g/L; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 217 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.15 mmol/L; Albumin 38 g/L; Total Protein 5.6 g/dL; Glucose 4.4 mmol/L.
- Day 348 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.38 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.07 mg/dL; Immunoglobulin G 9.88 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.53 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 5.9 ×10⁹/L; Absolute Neutrophil 3.5 ×10⁹/L; Platelets 245 ×10⁹/L; Creatinine 76 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.4 g/dL; Glucose 5.5 mmol/L.
- Day 446 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.71 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.39 mg/dL; Immunoglobulin G 10.4 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.42 g/L; Lactate Dehydrogenase 2.18 µkat/L; Hemoglobin 9.24 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.5 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 72.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.38 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 4.9 mmol/L.
- Day 551 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.98 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 1.01 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 2.13 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 155 ×10⁹/L; Creatinine 91.1 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.28 mmol/L; Albumin 43 g/L; Total Protein 6.5 g/dL; Glucose 6.11 mmol/L.
- Day 645 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.92 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.19 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 1.21 g/L; Immunoglobulin M 0.44 g/L; Lactate Dehydrogenase 1.93 µkat/L; Hemoglobin 9.61 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 247 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.3 mmol/L; Albumin 45 g/L; Total Protein 6.7 g/dL; Glucose 4.84 mmol/L.
- Day 726 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.62 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.25 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 1.42 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 1.98 µkat/L; Hemoglobin 9.49 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.7 ×10⁹/L; Platelets 191 ×10⁹/L; Creatinine 102 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 6.7 g/dL; Glucose 5.28 mmol/L.
- Day 807 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.59 mg/dL; Immunoglobulin G 10.7 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.28 g/L; Lactate Dehydrogenase 2.73 µkat/L; Hemoglobin 9.11 mmol/L; Leukocytes 4.5 ×10⁹/L; Absolute Neutrophil 2.4 ×10⁹/L; Platelets 170 ×10⁹/L; Creatinine 77.8 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.25 mmol/L; Albumin 40 g/L; Total Protein 6.8 g/dL; Glucose 4.62 mmol/L.

Other clinical attributes
- Day -16: Weight: 83 kg; Height: 175 cm.

Family history
- Relative with cancer history: yes; Relationship type: Maternal Grandmother; Relationship primary diagnosis: Breast Cancer; Relationship sex at birth: female.
- Relative with cancer history: yes; Relationship type: Maternal Grandfather; Relationship primary diagnosis: Lung Cancer; Relationship sex at birth: male.

Biospecimens (2 samples)
- Sample MMRF_2237_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -16 days.
- Sample MMRF_2237_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -16 days.
